Surgical pathology report (de-identified scan), TCGA case TCGA-EI-7004, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-7004-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – rectum and sigmoid colon.**

Unit in charge:

Physician in charge:

Material collected

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectosigmoid junction.**

Examination performed on:

Macroscopic description:

A 26 cm length of the large intestine with a piece of mesentery and periintestinal tissue sized 20 x 11.7 cm. A tumour sized 1.6 x 1 x 1.8 cm found in the mesentery. A flat tumour sized 7.8 x 2 x 0.6 cm found in the mesentery infiltrating the whole thickness of the intestine. The lesion surrounds 100% of the intestine circumference and narrows its lumen, is located 14.5 cm away from one of the excision lines and 4.3 cm from the other one. Minimum side margin is 3 cm.

Neighbouring lymph nodes are metastatic in gross appearance forming concretions

Microscopic description:

Adenocarcinoma mucocellulare et mucinosum (G3). Infiltratio carcinomatosa profunda tunicae muscularis priopriae et serosae flexure coli (sigmoideo - rectalis) et telae adiposae mesenterii et mesorecti.

Intestine ends clear of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (NO XXX/XXX).

Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

The number of lymph nodes difficult to assess due to the concretions.

Histopathology diagnosis:

Adenocarcinoma mucocellulare et mucinosum flexure sigmoideo - rectalis. Mucocellular and mucinous adenocarcinoma of sigmoid rectal junction

Metastases carcinomatosae in lymphonodis. Cancer metastases in the lymph nodes (No XXX/XXX). (G3, Dukes C, Atler - Coller C2, pT4, pN2b).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 80260177-80dc-4798-a095-375a9f21e39d (TCGA-EI-7004.13591EED-30E5-47A3-91BE-7A370663D2D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).